Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A2MK, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A2MK-06A (Metastatic).

[page 1 of 2]
PathNet History Upload External
Client

DOB/Age/Sex:

Location:

Requested by:

Requested on:

Specimen Rcvd:

Accession No.:

Copies to: N/A

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

HISTORICAL REQUEST DETAILS

CLINICAL NOTES

Metastatic melanoma

SPECIMEN INFORMATION

Left inguinal block dissection & left external iliac lymph node mass.
Lt ileo-inguinal dissection & e/o of recurrence Lt thigh.

1. Lt thigh mass. 2. LIF mass. 3. Lt ext. iliac & common iliac nodes.
4. Lt obturator nodes.

MACROSCOPIC DESCRIPTION

Four specimens received.

I. "Left inguinal block dissection". An ellipse of skin, 300 x 55mm with attached underlying subcutaneous tissue 310 x 80mm to a depth of 90mm. No abnormality of the skin surface is seen. No orientation has been given. In the centre of the subcutaneous fat there is a nodule 65 x 55 x 40mm. The nodule has a variegated tan and a cream cut surface with areas of darker tan. It appears well circumscribed and is 30mm from the skin surface. The mass appears to consist of 3-4 matted nodes. Two other smaller nodes were found but, despite careful and repeated examination, no further lymph nodes could be identified.

A-C. Representative sections through largest nodule.

D-F. All of second node.

G. Smallest node.

II. "Left external iliac lymph node mass". An irregular ovoid mass 140 x 85 x 80mm. The mass appears ?encapsulated and has a moderate amount of attached haemorrhagic tissue. On serial slicing the mass has a variegated tan cream and dark tan cut surface. Representative sections embedded in blocks A-C.

III. "Left obturator lymph node". An irregular piece of congested fatty tissue 50 x 40 x 15mm was examined for lymph nodes and masses.

- A. 3 nodes.
B. 2 nodes.
C. 3 nodes.
D. 2 nodes.
E&F. 1 node in two pieces.
G. 1 node in two pieces.
H&J. 1 node in two pieces.

ICB-0-3
Melanoma, NOS 8720/3
Site: lymph node, inguinal
C 77.4
lw 8/24/11

	lw 8/24/11	

[page 2 of 2]
Requested by: N/A

MRN/Name:

Location:

Accession:

ARCHIVAL HISTOPATHOLOGY REPORT

Accession Number:

Collected Date:

IV. "Left external block common iliac node". An irregular haemorrhagic piece of ragged soft fatty tissue approximately 100 x 40 x 20mm. The specimen was examined for lymph nodes and masses.

- A. 4 nodes.
- B. 3 nodes.
- C. 2 nodes.
- D. 2 nodes.
- E. 1 node.
- F. 1 node.
- G. 2 nodes.
- H. 1 node in two pieces.
- J&K. 1 node in two pieces.
- L&M. 1 node in two pieces.
- N-P. 1 node in three pieces.
- Q-S. 1 node in three pieces.

MICROSCOPIC REPORT

I. "Left inguinal block dissection". The large nodule show massive replacement of lymph nodes by deposits of spindle cells consistent with metastatic melanoma. No evidence of malignancy is seen in the other two nodes.

II. "Left external iliac lymph node mass". Metastatic malignant melanoma, more pleomorphic and epithelioid than in Specimen I and showing considerable necrosis.

III. "Left obturator lymph node". & IV. "Left external block common iliac node". No evidence of malignancy seen in any of the lymph nodes examined.

Electronic signature

Verified b

SUMMARY / KEY WORDS

Lymph node, inguinal - malignant melanoma, metastatic.
Haematopathology resection

Source: NCI Genomic Data Commons file fb6e0782-13fa-4444-b3c2-9ac081629fe7 (TCGA-EE-A2MK.8517BF69-FC60-4BAC-B034-E7D5B43627BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).